Somatic mutation profile of tumor specimen 0DJILO from CCDI case PBBWUK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Spinal cord; Age at diagnosis: 4.0 years (1,478 days).
Specimen 0DJILO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d8c0e9e-3336-4b1a-93c3-8bd2707630c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJIKR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c863fd1-9dd7-44fa-b02e-a4174514e891

The open-access MAF lists 83 somatic variants for this specimen: 52 protein-altering or splice-affecting, 15 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 15, Intron 8, 3'UTR 5, 5'UTR 3, Splice Site 3, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTL9 | c.373G>C p.A125P | Missense Mutation (SNP) | VAF 118/339 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV61005218; called by muse, mutect2, varscan2
- ADPGK | c.101C>G p.S34C | Missense Mutation (SNP) | VAF 109/391 reads (28%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.442); catalogued as rs781597770; called by muse, mutect2, varscan2
- CFAP46 | c.3257C>T p.T1086M | Missense Mutation (SNP) | VAF 186/651 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1284980964; called by mutect2, varscan2
- EMX2 | c.385T>C p.Y129H | Missense Mutation (SNP) | VAF 193/580 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.719); catalogued as rs745507404; called by muse, mutect2, varscan2
- GALNT14 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 54/765 reads (7%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.973); catalogued as rs150049844; called by muse, mutect2
- HDAC8 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 57/1238 reads (5%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV101002338; called by muse, mutect2
- HIVEP1 | c.6323G>C p.R2108P | Missense Mutation (SNP) | VAF 380/1338 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV65104977; called by muse, mutect2, varscan2
- MAP3K4 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 313/940 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs758235553; called by muse, mutect2, varscan2
- NCOA1 | c.727C>G p.L243V | Missense Mutation (SNP) | VAF 22/823 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV56054930; called by muse, mutect2
- OR2L5 | c.773A>G p.Y258C | Missense Mutation (SNP) | VAF 342/985 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs1206272935; called by muse, mutect2, varscan2
- RHOXF2 | c.373G>A p.V125I | Missense Mutation (SNP) | VAF 216/712 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs202000800; called by muse, mutect2, varscan2
- RYR3 | c.7571G>A p.G2524E (on ENST00000389232; = p.G2525E on NM_001036.6) | Missense Mutation (SNP) | VAF 412/1132 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs1414834476; called by muse, mutect2, varscan2
- SAMD9L | c.58A>T p.K20* | Nonsense Mutation (SNP) | VAF 474/1438 reads (33%) | catalogued as COSV59083091; called by muse, mutect2, varscan2
- SPP2 | c.169A>G p.S57G | Missense Mutation (SNP) | VAF 72/1441 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.184); catalogued as COSV99394483; called by muse, mutect2
- STK26 | c.628A>G p.I210V | Missense Mutation (SNP) | VAF 372/1228 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); catalogued as rs148760250; called by muse, mutect2, varscan2
- TJP2 | c.1151A>G p.D384G | Missense Mutation (SNP) | VAF 160/1160 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1329797754; called by muse, mutect2, varscan2
- TSPOAP1 | c.1422+1G>A p.X474_splice | Splice Site (SNP) | VAF 28/670 reads (4%) | catalogued as COSV99270217; called by muse, mutect2
- ACP4 | c.220G>A p.G74R | Missense Mutation (SNP) | VAF 91/299 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM33 | c.410G>A p.S137N | Missense Mutation (SNP) | VAF 32/974 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); called by muse, mutect2
- AP1S3 | c.152A>C p.D51A | Missense Mutation (SNP) | VAF 30/1043 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.182); called by muse, mutect2
- AXIN1 | c.598T>C p.S200P | Missense Mutation (SNP) | VAF 64/846 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); called by muse, mutect2
- C1orf127 | c.1100G>T p.G367V | Missense Mutation (SNP) | VAF 213/614 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP128 | c.2614-2A>G p.X872_splice | Splice Site (SNP) | VAF 128/340 reads (38%) | called by muse, varscan2
- DCLRE1A | c.772G>T p.A258S | Missense Mutation (SNP) | VAF 119/1686 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.057); called by muse, mutect2
- ECE1 | c.2119T>C p.F707L | Missense Mutation (SNP) | VAF 30/670 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- ECE2 | c.25G>A p.G9R | Missense Mutation (SNP) | VAF 248/724 reads (34%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FGF12 | c.561C>A p.N187K (on ENST00000454309 / NM_021032.5; = p.N125K on NM_004113.6) | Missense Mutation (SNP) | VAF 400/1294 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FNTA | c.470C>A p.A157E | Missense Mutation (SNP) | VAF 344/1122 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IKBKE | c.52G>C p.G18R | Missense Mutation (SNP) | VAF 20/646 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IKZF4 | c.652C>G p.P218A | Missense Mutation (SNP) | VAF 379/1061 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- INF2 | c.881T>C p.V294A | Missense Mutation (SNP) | VAF 297/884 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- KCP | c.3478C>G p.R1160G (on ENST00000620378; = p.R1284G on NM_001366122.1) | Missense Mutation (SNP) | VAF 56/909 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.225); called by muse, mutect2
- LBX1 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 189/559 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- LRP3 | c.331C>G p.P111A | Missense Mutation (SNP) | VAF 138/454 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- LYG1 | c.244G>C p.D82H | Missense Mutation (SNP) | VAF 381/1152 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAPK4 | c.1251G>T p.E417D | Missense Mutation (SNP) | VAF 107/384 reads (28%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- MGLL | c.116G>T p.G39V (on ENST00000398104 / NM_001003794.2; = p.G49V on NM_007283.6) | Missense Mutation (SNP) | VAF 212/943 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MST1 | c.923C>G p.T308R | Missense Mutation (SNP) | VAF 333/1354 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NALCN | c.1087G>C p.A363P | Missense Mutation (SNP) | VAF 388/1256 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NPHS1 | c.1626G>A p.Q542= | Splice Region (SNP) | VAF 166/537 reads (31%) | called by muse, mutect2, varscan2
- NUDT11 | c.225G>T p.K75N | Missense Mutation (SNP) | VAF 38/806 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.009); called by muse, mutect2
- NXF3 | c.996+1G>A p.X332_splice | Splice Site (SNP) | VAF 106/1632 reads (6%) | called by muse, mutect2
- OR10V1 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 371/1182 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCMTD2 | c.732G>C p.Q244H | Missense Mutation (SNP) | VAF 90/1057 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2
- PLCE1 | c.3344G>A p.C1115Y | Missense Mutation (SNP) | VAF 409/1206 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRICKLE2 | c.1381A>C p.N461H (on ENST00000295902; = p.N405H on NM_198859.4) | Missense Mutation (SNP) | VAF 288/848 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- SLAMF1 | c.883G>T p.D295Y | Missense Mutation (SNP) | VAF 99/1388 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2
- STK26 | c.1000G>T p.D334Y | Missense Mutation (SNP) | VAF 84/1301 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.092); called by muse, mutect2
- TCP11 | c.1044G>T p.L348F (on ENST00000512012; = p.L286F on NM_018679.5) | Missense Mutation (SNP) | VAF 428/1248 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- TCTN3 | c.842C>T p.T281I | Missense Mutation (SNP) | VAF 416/1208 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ZNF578 | c.1744T>G p.S582A | Missense Mutation (SNP) | VAF 26/572 reads (5%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.006); called by muse, mutect2
- ZNF831 | c.88C>G p.Q30E | Missense Mutation (SNP) | VAF 209/667 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by mutect2, varscan2
- ATP2B1 | c.486T>C p.S162= | Silent (SNP) | VAF 547/1531 reads (36%) | called by muse, mutect2, varscan2
- C3orf20 | c.588C>T p.A196= | Silent (SNP) | VAF 169/1195 reads (14%) | catalogued as rs375504473; called by muse, mutect2, varscan2
- FFAR1 | c.759A>T p.L253= | Silent (SNP) | VAF 23/486 reads (5%) | called by muse, mutect2
- FLT3 | c.756T>C p.T252= | Silent (SNP) | VAF 326/967 reads (34%) | called by muse, mutect2, varscan2
- IRS4 | c.1320A>G p.P440= | Silent (SNP) | VAF 198/529 reads (37%) | called by muse, mutect2, varscan2
- JPH2 | c.471G>A p.S157= | Silent (SNP) | VAF 51/698 reads (7%) | catalogued as rs1228982207, COSV65904828; called by muse, mutect2
- LAMB2 | c.4773G>T p.R1591= | Silent (SNP) | VAF 328/908 reads (36%) | catalogued as rs771035328; called by muse, mutect2, varscan2
- NKX2-4 | c.813C>T p.S271= | Silent (SNP) | VAF 62/816 reads (8%) | called by muse, mutect2
- OPRM1 | c.45T>C p.D15= | Silent (SNP) | VAF 57/1125 reads (5%) | catalogued as rs1266366788; called by muse, mutect2
- SCRIB | c.3040C>T p.L1014= | Silent (SNP) | VAF 104/1142 reads (9%) | catalogued as rs1554635764; called by muse, mutect2
- SMG7 | c.3318C>G p.S1106= | Silent (SNP) | VAF 255/1152 reads (22%) | catalogued as COSV61630374; called by muse, mutect2, varscan2
- SUGP1 | c.528G>A p.L176= | Silent (SNP) | VAF 142/441 reads (32%) | catalogued as rs771544715; called by muse, mutect2, varscan2
- TDRD6 | c.1188G>A p.L396= | Silent (SNP) | VAF 257/715 reads (36%) | catalogued as COSV100288091; called by muse, mutect2, varscan2
- TLR3 | c.2433A>G p.R811= | Silent (SNP) | VAF 348/1030 reads (34%) | called by muse, mutect2, varscan2
- TMC8 | c.1374C>T p.G458= | Silent (SNP) | VAF 50/724 reads (7%) | called by muse, mutect2
- BOP1 | c.1424+35G>A | Intron (SNP) | VAF 210/586 reads (36%) | called by muse, mutect2, varscan2
- C11orf52 | c.32+47G>A | Intron (SNP) | VAF 150/455 reads (33%) | called by muse, mutect2, varscan2
- C17orf49 | c.410-58G>C | Intron (SNP) | VAF 34/160 reads (21%) | called by muse, mutect2, varscan2
- CAPS | c.-23+33G>A | Intron (SNP) | VAF 157/421 reads (37%) | called by muse, mutect2, varscan2
- CD180 | c.-7G>C | 5'UTR (SNP) | VAF 178/475 reads (37%) | catalogued as COSV99842412; called by muse, mutect2, varscan2
- CREM | c.698-5479C>A | Intron (SNP) | VAF 46/146 reads (32%) | called by muse, mutect2, varscan2
- EML3 | c.*39C>T | 3'UTR (SNP) | VAF 46/722 reads (6%) | catalogued as rs1006678732; called by muse, mutect2
- ESYT3 | c.1435-100G>A | Intron (SNP) | VAF 22/65 reads (34%) | called by muse, mutect2, varscan2
- LSM14A | c.*123G>T | 3'UTR (SNP) | VAF 23/934 reads (2%) | called by muse, mutect2
- NR6A1 | c.-5A>T | 5'UTR (SNP) | VAF 86/224 reads (38%) | called by muse, mutect2, varscan2
- PNPLA8 | c.1625+32G>C | Intron (SNP) | VAF 150/416 reads (36%) | called by muse, mutect2, varscan2
- R3HDM2 | c.*43G>C | 3'UTR (SNP) | VAF 120/382 reads (31%) | called by muse, varscan2
- SLC25A44 | c.*40C>A | 3'UTR (SNP) | VAF 35/325 reads (11%) | called by muse, mutect2, varscan2
- SS18L1 | c.-25A>G | 5'UTR (SNP) | VAF 101/251 reads (40%) | called by muse, mutect2, varscan2
- TUBB | c.58-652G>T | Intron (SNP) | VAF 51/545 reads (9%) | called by muse, mutect2
- WNT8B | c.*13C>A | 3'UTR (SNP) | VAF 198/673 reads (29%) | called by muse, mutect2, varscan2
